Gene-level copy-number profile of tumor specimen ALCH-B2T1-TTP1-A from ALCHEMIST case ALCH-B2T1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.4 years (23,517 days).
Specimen ALCH-B2T1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1f723db8-a312-49a7-acc7-2def78f5069a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2T1-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/cb3941f7-7c9b-43a3-8d2a-70f13ced2675

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 20,443; copy number 2: 27,885; copy number 3: 7,445; copy number 4: 937; copy number 5: 1,489; copy number 6: 29; copy number 7: 12; copy number 8: 16; copy number 9: 30; copy number 11: 1; copy number 12: 40; copy number 14: 2; copy number 15: 1; copy number 16: 10; copy number 19: 1; copy number 20: 5; copy number 21: 4; copy number 22: 1; copy number 23: 1; copy number 29: 1; copy number 35: 12.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:120,211,054–120,217,279, 6 genes (within-gene range 0–1): MTATP6P26, MTCO3P43, MTND3P10, MTND4LP14, MTND4P26, MTND5P28.
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr5:135,038,831–135,040,047, 1 gene (within-gene range 0–2): C5orf66-AS1.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr9:63,581,254–63,581,834, 1 gene: AL591438.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,655 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:725,885–915,976, 16 genes, copy number 5 (within-gene range 4–5): AL669831.1, RNU6-1199P, AL669831.2, LINC01409, AL669831.6, AL669831.4, FAM87B, LINC01128, LINC00115, AL669831.7, FAM41C, TUBB8P11, AL669831.5, AL645608.6, AL645608.2, AL645608.4.
- chr3:180,989,762–181,836,880, 1 gene, copy number 16 (within-gene range 1–21): SOX2-OT.
- chr3:181,372,732–183,116,075, 31 genes, copy number 11–23: AC068308.1, RPL7AP25, AC125613.1, AC125613.2, AC117415.1, SOX2, AC117415.2, RN7SL703P, RNA5SP150, AC007547.2, AC007547.1, LINC01206, RN7SKP265, AC012081.1, AC084211.1, LINC01994, EIF4EP3, LINC01995, AC021055.1, RPL7L1P8, LINC02031, AC083801.1, AC083801.2, AC069431.1, ATP11B, AC069431.2, AC092953.2, DCUN1D1, AC092953.1, MCCC1, MCCC1-AS1.
- chr8:47,736,913–47,738,164, 1 gene, copy number 5: CEBPD.
- chr8:62,110,524–71,702,786, 140 genes, copy number 5 (broad region; genes not listed).
- chr8:73,008,856–73,048,123, 1 gene, copy number 5 (within-gene range 4–5): TERF1.
- chr8:73,042,910–134,881,899, 881 genes, copy number 5–7 (broad region; genes not listed).
- chr8:140,657,900–141,195,808, 7 genes, copy number 5: PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1.
- chr8:144,930,358–145,066,685, 8 genes, copy number 5: ZNF16, ZNF252P, AF235103.1, TMED10P1, ZNF252P-AS1, AF235103.2, AC139103.1, C8orf33.
- chr11:1,752,752–1,778,388, 4 genes, copy number 6–15 (within-gene range 4–15): CTSD, AC068580.3, AC068580.1, AC068580.2.
- chr12:21,047,179–21,239,796, 2 genes, copy number 14 (within-gene range 2–14): AC022335.1, SLCO1B1.
- chr12:68,248,242–68,850,686, 23 genes, copy number 12 (within-gene range 2–12): IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2.
- chr14:18,333,726–18,341,859, 1 gene, copy number 8: CR383658.1.
- chr14:18,418,775–18,419,273, 1 gene, copy number 7: BNIP3P6.
- chr16:10,760,919–16,143,257, 148 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr16:16,223,027–16,300,806, 2 genes, copy number 5–35 (within-gene range 3–35): AC136624.1, NOMO3.
- chr16:16,290,135–16,398,594, 14 genes, copy number 6–35: AC136624.2, MIR3179-2, MIR3670-2, AC138969.2, MIR3180-2, PKD1P1, Y_RNA, AC138969.1, MIR6511A2, MIR6770-2, AC138969.3, MIR6511A3, NPIPA7, AC136619.1.
- chr16:28,342,555–28,455,356, 7 genes, copy number 12: NPIPB6, AC138894.3, EIF3CL, MIR6862-1, CDC37P2, AC138894.4, AC138894.2.
- chr16:29,380,242–30,445,874, 89 genes, copy number 5–8 (broad region; genes not listed).
- chr18:62,650,308–68,114,878, 54 genes, copy number 5: RN7SL705P, PHLPP1, RNU6-142P, BCL2, AC022726.1, AC022726.2, KDSR, AC036176.1, VPS4B, AC036176.2, SERPINB5, AC036176.3, ATP5MC1P6, SERPINB12, SERPINB13, SERPINB4, SERPINB11, SERPINB3, SERPINB7, SERPINB2, SERPINB10, HMSD, AC009802.1, SERPINB8, LINC01924, RPL12P39, LINC00305, LINC01538, AC027506.1, AC007948.1, AC007631.1, LINC01916, AC090358.1, CDH7, AC023394.2, AC023394.1, PRPF19P1, CDH19, RNU6-1037P, MIR5011, RPL31P9, AC091042.1, AC110597.1, DSEL, AC110597.3, AC114689.3, AC022662.1, AC022655.1, FAM32DP, AC114689.1, LINC01903, AC114689.2, AC100844.1, AC068112.1.
- chr18:68,258,080–68,278,243, 2 genes, copy number 5: LINC01912, AC022968.1.
- chr19:1,782,075–2,096,673, 22 genes, copy number 9 (within-gene range 1–9): ATP8B3, REXO1, AC012615.2, MIR1909, AC012615.6, AC012615.3, KLF16, AC012615.4, AC012615.1, AC012615.5, ABHD17A, SCAMP4, ADAT3, CSNK1G2, CSNK1G2-AS1, BTBD2, AC005306.1, AC004678.2, AC004678.1, AC007136.1, MKNK2, MOB3A.
- chr19:32,875,925–33,815,763, 27 genes, copy number 5: CEP89, RPL31P60, FAAP24, RHPN2, AC008521.1, AC008521.2, GPATCH1, WDR88, LRP3, AC008738.1, AC008738.7, SLC7A10, AC008738.4, AC008738.6, AC008738.3, CEBPA, AC008738.5, CEBPA-DT, AC008738.2, RPS3AP50, AKR1B1P7, CEBPG, PEPD, AC010485.1, RPL21P131, CHST8, KCTD15.
- chr19:39,254,916–39,520,686, 19 genes, copy number 5: MSRB1P1, IFNL4P1, IFNL2, IFNL1, LRFN1, GMFG, AC011445.1, SAMD4B, RN7SL566P, PAF1, MED29, ZFP36, MIR4530, PLEKHG2, RPS16, SUPT5H, TIMM50, DLL3, SELENOV.
- chr19:39,943,239–40,122,168, 9 genes, copy number 5: PRR13P5, PSMC4, ZNF546, AC007842.1, ZNF780B, AC005614.2, ZNF780A, AC005614.1, VN1R96P.
- chr19:40,299,478–40,465,764, 15 genes, copy number 5: RNU6-945P, C19orf47, Y_RNA, Y_RNA, PLD3, AC118344.2, MIR6796, HIPK4, PRX, SERTAD1, AC010271.2, SERTAD3, AC010271.1, BLVRB, Metazoa_SRP.
- chr21:14,485,228–18,967,058, 68 genes, copy number 5 (broad region; genes not listed).
- chr21:23,857,081–27,751,233, 56 genes, copy number 5–9: AP000474.2, AP000474.1, AP000477.2, AP000477.3, AP000477.1, AP000470.1, LINC01689, LINC01684, LINC01692, AP000402.1, AP000146.1, AP001342.1, AP000235.1, AP000233.2, RN7SKP236, AP000233.1, AP001341.1, RNA5SP489, RPL13AP7, AP001340.1, LINC00158, AP000221.1, MIR155HG, MIR155, AP000223.1, MRPL39, JAM2, RNGTTP1, AP000224.1, FDX1P2, ATP5PF, GABPA, LLPHP2, APP, AP001442.1, RNU6-123P, AP001439.1, AP000229.1, RNU6-926P, AP001595.1, AP001596.1, CYYR1-AS1, AP001596.2, CYYR1, ADAMTS1, AP001599.1, ADAMTS5, MIR4759, GPX1P2, AP001605.1, AP001604.1, EIF4A1P1, RPL10P1, NCSTNP1, LINC01673, LINC00113.
- chr22:18,636,445–18,638,405, 1 gene, copy number 8: CA15P2.
- chr22:18,846,811–18,861,049, 2 genes, copy number 5 (within-gene range 5–7): AC008132.1, BCRP7.
- chr22:21,141,624–21,142,371, 1 gene, copy number 6: E2F6P2.
- chr22:21,370,064–21,379,701, 2 genes, copy number 9–29: AP000552.1, Metazoa_SRP.

Autosomal genes at a single copy (total copy number 1): 20,443. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
